Somatic mutation profile of tumor specimen TCGA-2F-A9KQ-01A (aliquot TCGA-2F-A9KQ-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.2 years (25,259 days).
Specimen TCGA-2F-A9KQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a56963-7c17-477a-acff-11874d854b10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KQ-11A (Solid Tissue Normal), aliquot TCGA-2F-A9KQ-11A-11D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc462b84-6160-4f17-84d1-b2b0e23001e7

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 3, Splice Region 1, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 72/157 reads (46%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 40/46 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1327C>T p.R443C (on ENST00000372530 / NM_001198934.2; = p.R400C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as rs866831212, COSV55093460; called by muse, mutect2, varscan2
- ACAP3 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs1158470503, COSV57644233; called by muse, mutect2, varscan2
- AFF4 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.445); catalogued as rs201192755, COSV54799260; called by muse, mutect2, varscan2
- AKAP6 | c.3005A>G p.Y1002C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV55230768; called by muse, mutect2, varscan2
- CD1D | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as COSV63809940; called by muse, mutect2, varscan2
- CDKN1A | c.47del p.K16Rfs*15 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1181490956; called by pindel, varscan2
- CKAP4 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs970921635, COSV65173185; called by muse, mutect2, varscan2
- CRIP1 | c.193+2T>C p.X65_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100322359; called by muse, varscan2
- DEFB116 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs553935240, COSV68722428; called by muse, mutect2, varscan2
- DENND2B | c.1717C>T p.H573Y | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58207487; called by muse, mutect2, varscan2
- DNMBP | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV60632188; called by muse, mutect2
- ERBB4 | c.2561C>G p.P854R | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61518595, COSV61534070; called by muse, mutect2, varscan2
- FCHO1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs534109677, COSV53182715, COSV99405900; called by muse, mutect2, varscan2
- FMNL1 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754579127, COSV58958922; called by muse, mutect2, varscan2
- H3-3A | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV100831348; called by muse, mutect2, varscan2
- HIF1A | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60191166; called by muse, mutect2, varscan2
- KBTBD4 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.953); catalogued as rs746451387, COSV58596665; called by muse, mutect2, varscan2
- KPNB1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV51600269; called by muse, mutect2, varscan2
- KRIT1 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1417106399, COSV60667331, COSV60670287; called by muse, mutect2, varscan2
- LLGL2 | c.2603C>G p.T868S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV51398722; called by muse, mutect2, varscan2
- MLXIP | c.1712A>C p.K571T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as COSV59837703; called by muse, mutect2, varscan2
- MPRIP | c.2364G>T p.E788D | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV57930104; called by muse, mutect2, varscan2
- MYOZ2 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV61086071; called by muse, mutect2, varscan2
- NLRP4 | c.2364C>A p.F788L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV56715619, COSV56722096; called by muse, mutect2, varscan2
- PCDHA7 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554135772, COSV65343760, COSV65346769; called by muse, mutect2, varscan2
- PCDHGA7 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs919957351, COSV53941030; called by muse, mutect2, varscan2
- PPARG | c.490C>T p.R164W (on ENST00000287820 / NM_015869.5; = p.R134W on NM_005037.7) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170672782, CM148624, COSV55144655; called by muse, mutect2, varscan2
- RAI1 | c.2767G>T p.E923* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99884841; called by muse, mutect2, varscan2
- RBM25 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56202454; called by muse, mutect2, varscan2
- ROS1 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV63861050; called by muse, mutect2, varscan2
- RPTOR | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60817207; called by muse, mutect2, varscan2
- SERPINI1 | c.484C>T p.L162= | Splice Region (SNP) | VAF 39/72 reads (54%) | catalogued as COSV55514420; called by muse, mutect2, varscan2
- SHC1 | c.700C>G p.L234V (on ENST00000368445 / NM_183001.5; = p.L124V on NM_003029.5) | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.727); catalogued as COSV63535138; called by muse, mutect2, varscan2
- SLC4A4 | c.277C>T p.R93* (on ENST00000264485 / NM_001098484.3; = p.R49* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 69/191 reads (36%) | catalogued as COSV52627802; called by muse, mutect2, varscan2
- SMARCD2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1489101718, COSV99856591; called by muse, mutect2, varscan2
- SPTAN1 | c.6757C>T p.Q2253* | Nonsense Mutation (SNP) | VAF 13/14 reads (93%) | catalogued as COSV100823933; called by muse, mutect2, varscan2
- STT3B | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV55505682; called by muse, mutect2, varscan2
- SYNE1 | c.19904A>G p.Q6635R (on ENST00000367255 / NM_182961.4; = p.Q6564R on NM_033071.3) | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55085949; called by muse, mutect2, varscan2
- TMEM165 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67262593; called by muse, varscan2
- TMEM67 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV60043838; called by muse, mutect2, varscan2
- TTN | c.28866A>T p.E9622D (on ENST00000591111; = p.E8695D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/26 reads (85%) | PolyPhen benign (0.109); catalogued as COSV60305763; called by muse, mutect2, varscan2
- TTN | c.25273C>T p.L8425F (on ENST00000591111; = p.L7498F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | PolyPhen possibly damaging (0.663); catalogued as COSV60305775; called by muse, mutect2, varscan2
- UACA | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV59859414; called by muse, mutect2, varscan2
- UGT3A2 | c.1394C>G p.T465R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV56933044; called by muse, mutect2, varscan2
- UPF2 | c.2870A>G p.K957R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.31); catalogued as COSV62661984; called by muse, mutect2, varscan2
- VIM | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs762391438, COSV56405167; called by muse, mutect2, varscan2
- WDR36 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs749152140, COSV72411464; called by muse, mutect2, varscan2
- WDR37 | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV54131402; called by muse, mutect2, varscan2
- ZBED9 | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV71729746; called by muse, mutect2, varscan2
- CDKN1A | c.68dup p.V25Sfs*11 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by pindel, varscan2
- ASPHD1 | c.1032C>T p.D344= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs191778761, COSV58157971; called by muse, mutect2, varscan2
- BCL11B | c.1749G>A p.A583= (on ENST00000357195 / NM_001282237.2; = p.A512= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs760702497, COSV61735564; called by muse, mutect2, varscan2
- DNAH3 | c.3597G>A p.L1199= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV54547660; called by muse, mutect2, varscan2
- ELOA | c.1311C>T p.L437= | Silent (SNP) | VAF 94/235 reads (40%) | catalogued as COSV101403799, COSV69311265; called by muse, mutect2, varscan2
- GNAS | c.924G>A p.P308= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58345151; called by muse, mutect2, varscan2
- LRRC4 | c.153G>A p.S51= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs762943168, COSV50813643; called by muse, mutect2, varscan2
- LSM14A | c.828G>A p.R276= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV70885644; called by muse, mutect2, varscan2
- MACROD2 | c.183A>G p.T61= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV54045990; called by muse, varscan2
- NPHP3 | c.1914G>A p.L638= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs1168819035, COSV58633102; called by muse, mutect2, varscan2
- PLEKHG6 | c.1368C>T p.L456= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV50610832; called by muse, mutect2, varscan2
- PUSL1 | c.510G>A p.Q170= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1400223467, COSV60090205; called by muse, mutect2, varscan2
- SIGLEC8 | c.28C>T p.L10= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV58475607; called by muse, mutect2, varscan2
- SLC22A2 | c.12C>T p.T4= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs750094931, COSV65265883; called by muse, mutect2, varscan2
- TXNDC16 | c.2403T>C p.N801= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV55987059; called by muse, mutect2, varscan2
- VSIG4 | c.126C>T p.T42= | Silent (SNP) | VAF 38/41 reads (93%) | catalogued as COSV66074830; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446374 G>C | 3'Flank (SNP) | VAF 101/220 reads (46%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.250C>T | RNA (SNP) | VAF 20/21 reads (95%) | catalogued as rs1329946594; called by muse, mutect2, varscan2
